MMRF case MMRF_1395 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/5d2836a9-633f-4403-b8cd-5861c132cee8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.5 years (23,544 days); ISS stage: I; Days to last known disease status: 1,432 days (3.9 years); Days to last follow up: 1,432 days (3.9 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 108 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 126 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 189 days; Days to treatment end: 190 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 191 days; Days to treatment end: 191 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,156 days (3.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -32 (ECOG 1): M Protein 2.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.72 mg/dL; Immunoglobulin G 37.2 g/L; Immunoglobulin A 1.01 g/L; Immunoglobulin M 0.43 g/L; Beta 2 Microglobulin 2.34 µg/mL; Hemoglobin 7.56 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.15 mmol/L; Albumin 38 g/L; Total Protein 8.7 g/dL; Glucose 6.66 mmol/L.
- Day 67 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.2 mg/dL; Immunoglobulin G 3.74 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.04 g/L; Hemoglobin 8 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 113 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.03 mmol/L; Albumin 38 g/L; Total Protein 5.6 g/dL; Glucose 6.66 mmol/L.
- Day 151 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.23 mg/dL; Immunoglobulin G 2.59 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.13 mmol/L; Albumin 45 g/L; Total Protein 5.7 g/dL; Glucose 5.01 mmol/L.
- Day 243 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.21 mg/dL; Immunoglobulin G 4.2 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 44 g/L; Total Protein 5.9 g/dL; Glucose 4.73 mmol/L.
- Day 317 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Immunoglobulin G 4.12 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 6.1 g/dL; Glucose 5.72 mmol/L.
- Day 401 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Immunoglobulin G 4.74 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 6 g/dL; Glucose 5.39 mmol/L.
- Day 506 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.31 mg/dL; Immunoglobulin G 5.71 g/L; Hemoglobin 8 mmol/L; Leukocytes 3.3 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 46 g/L; Total Protein 6.3 g/dL; Glucose 5.61 mmol/L.
- Day 569 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.32 mg/dL; Immunoglobulin G 6.5 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 4.1 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.4 mmol/L; Albumin 48 g/L; Total Protein 6.6 g/dL; Glucose 5.34 mmol/L.
- Day 689 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Immunoglobulin G 7.26 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 47 g/L; Total Protein 6.6 g/dL; Glucose 5.61 mmol/L.
- Day 752 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 7.16 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.4 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 46 g/L; Total Protein 6.2 g/dL; Glucose 5.56 mmol/L.
- Day 844 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Immunoglobulin G 7.21 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.41 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.4 mmol/L; Albumin 46 g/L; Total Protein 6.5 g/dL; Glucose 5.06 mmol/L.
- Day 938 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.72 mg/dL; Immunoglobulin G 7.71 g/L; Hemoglobin 8.8 mmol/L; Leukocytes 4.9 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.4 mmol/L; Albumin 48.7 g/L; Total Protein 6.9 g/dL; Glucose 5.12 mmol/L.
- Day 1,027 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.66 mg/dL; Immunoglobulin G 7 g/L; Hemoglobin 8.68 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.5 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 5.01 mmol/L.
- Day 1,132 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 7.16 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 9.11 mmol/L; Leukocytes 5.19 ×10⁹/L; Absolute Neutrophil 3.33 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.35 mmol/L; Albumin 49 g/L; Total Protein 6.8 g/dL; Glucose 6.77 mmol/L.
- Day 1,216: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 7.75 g/L; Beta 2 Microglobulin 0.33 µg/mL; Hemoglobin 8.49 mmol/L; Leukocytes 3.8 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 4.9 mmol/L.
- Day 1,317 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.4 mg/dL; Immunoglobulin G 8.35 g/L; Hemoglobin 8.68 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 5.39 mmol/L.
- Day 1,432 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Immunoglobulin G 9.07 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 130 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 45 g/L; Total Protein 6.6 g/dL; Glucose 5.39 mmol/L.

Other clinical attributes
- Day -32: Weight: 84 kg; Height: 175 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1395_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -32 days.
- Sample MMRF_1395_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -32 days.
